Surgical pathology report (de-identified scan), TCGA case TCGA-5P-A9JU, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University Hospital Erlangen, specimen TCGA-5P-A9JU-01A (Primary Tumor).

Papillary Renal Cell Carcinoma Type II with a diameter of 5 cm located in the medial section of a slide from a nephrectomy (left side). The tumor infiltrates the peripelvic fat layer, with additional tumoral structures in the kidney veins. Ureter and vascular surgical margins are free of tumor.

TNM 2010 Classification:

Stage: pT3a L0 V2 Pn0

Grade: Fuhrmann-Grade 3

R-classification: Local R0

ICD-O: 8260/3.

ICD-O-3
Carcinoma, papillary renal cell 8260/3
Site: L4 kidney NOS C64.9
J 26/13/14

Source: NCI Genomic Data Commons file 79e57aff-b33f-4fa9-ad05-8186d66d1711 (TCGA-5P-A9JU.229F266C-7F35-4B36-B07F-50A372EE9E6E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).